Gene-level copy-number profile of tumor specimen TCGA-56-8308-01A from TCGA case TCGA-56-8308, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 79.8 years (29,139 days).
Specimen TCGA-56-8308-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.fe7fa6b2-275c-455f-ba0a-64dd567a809a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-8308-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac85c593-52dc-45b8-b0c4-1d6e42c4e34f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 374; copy number 2: 16,664; copy number 3: 16,850; copy number 4: 19,006; copy number 5: 3,092; copy number 6: 1,414; copy number 7: 1,007; copy number 8: 757; copy number 9: 77; copy number 10: 44; copy number 11: 12; copy number 13: 66; copy number 16: 28; copy number 19: 31; copy number 20: 186; copy number 21: 2; copy number 26: 99; copy number 36: 7; copy number 37: 4; copy number 41: 20; copy number 50: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-8308-01A-11D-2292-01): tumor purity 0.44, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:56,975,593–61,232,040, 51 genes (within-gene range 0–2): AC114973.1, AC034244.1, AC034244.2, Y_RNA, GPBP1, AC025470.1, AC025470.2, SALL4P1, ACTBL2, LINCR-0003, AC008780.1, AC106822.1, LINC02225, LINC02101, AC008786.1, PGAM1P1, PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1, RPL5P15, AC008852.1, PDE4D, AC092343.1, AC008833.1, NDUFB4P2, MIR582, AC034234.1, RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1, AC109133.1, KRT8P31, ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1, NDUFAF2, AC008498.2, AC008498.1, SMIM15, SMIM15-AS1.
- chr9:21,802,636–22,824,213, 17 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 581 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:68,860,909–69,387,250, 12 genes, copy number 11 (within-gene range 8–11): BMP10, GKN3P, GKN2, GKN1, ANTXR1, AC114802.1, MIR3126, RNA5SP96, RNU6-1216P, AC112230.1, GFPT1, Y_RNA.
- chr3:168,249,522–168,830,599, 1 gene, copy number 26 (within-gene range 5–26): EGFEM1P.
- chr3:168,475,198–186,457,299, 319 genes, copy number 13–36 (broad region; genes not listed).
- chr11:35,579,430–39,261,213, 36 genes, copy number 19–50: AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1, AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P.
- chr11:68,754,620–71,252,577, 62 genes, copy number 10–20 (within-gene range 1–20) (broad region; genes not listed).
- chr11:80,321,620–86,765,467, 86 genes, copy number 9–37 (broad region; genes not listed).
- chr11:86,821,143–86,857,947, 4 genes, copy number 9: MOB4P2, OR7E13P, AP000654.1, OR7E2P.
- chr11:100,684,162–103,895,271, 60 genes, copy number 10–41: ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693.
- chr11:103,945,548–103,946,546, 1 gene, copy number 20: AP003043.1.

Autosomal genes at a single copy (total copy number 1): 366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
